Somatic mutation profile of tumor specimen 0DI202 from CCDI case PBBVFA, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Vital status: Alive; Primary diagnosis: Ependymoma, anaplastic; Tissue or organ of origin: Cerebrum; Age at diagnosis: 9.7 years (3,555 days).
Specimen 0DI202: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a1b035d9-4c09-42fb-b3d3-8c64c6d53e4e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DI1JV (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c6abaf91-bbb1-48a2-bd9d-90c63a23de3c

The open-access MAF lists 8 somatic variants for this specimen: 4 protein-altering or splice-affecting, 2 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 4, Silent 2, Intron 1, 3'Flank 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- G6PC | c.445C>T p.R149W | Missense Mutation (SNP) | VAF 92/264 reads (35%) | SIFT tolerated (0.46); PolyPhen benign (0); catalogued as rs779548820, COSV53831761; called by muse, varscan2
- PCDHA8 | c.1685C>T p.A562V | Missense Mutation (SNP) | VAF 34/260 reads (13%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.323); catalogued as COSV65327340; called by muse, varscan2
- SCUBE1 | c.736G>A p.A246T | Missense Mutation (SNP) | VAF 102/552 reads (18%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.471); catalogued as rs750810273, COSV99298199; called by muse, varscan2
- STK32B | c.779G>A p.R260K | Missense Mutation (SNP) | VAF 156/370 reads (42%) | SIFT tolerated (0.9); PolyPhen benign (0.003); called by muse, varscan2
- CYP3A4 | c.1557C>T p.P519= (on ENST00000336411; = p.P488= on NM_017460.6 and 1 other RefSeq transcript) | Silent (SNP) | VAF 390/858 reads (45%) | catalogued as rs756357832; called by muse, varscan2
- LZTS1 | c.1383G>A p.A461= | Silent (SNP) | VAF 91/254 reads (36%) | catalogued as rs35939758; called by muse, varscan2
- GNAL | chr18:11884708 A>G | 3'Flank (SNP) | VAF 12/41 reads (29%) | called by muse, varscan2
- IRF7 | c.493-25C>G | Intron (SNP) | VAF 39/298 reads (13%) | called by muse, varscan2
